MMRF case MMRF_2353 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9f5b0c9f-c38c-4fea-817e-efb3ba8c4404

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.0 years (20,807 days); ISS stage: I; Days to last known disease status: 809 days (2.2 years); Days to last follow up: 809 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 288 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 394 days (1.1 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 443 days (1.2 years); Days to treatment end: 443 days (1.2 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 444 days (1.2 years); Days to treatment end: 444 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -32 (ECOG 0): M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.863 mg/dL; Immunoglobulin G 55.4 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.85 µg/mL; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 3.81 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 10.6 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 0.07 mg/dL.
- Day 78: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.677 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 105 ×10⁹/L.
- Day 164 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 5.01 mmol/L.
- Day 227 (ECOG 0): M Protein 0.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.902 mg/dL; Immunoglobulin G 8.82 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 9.02 mmol/L.
- Day 316 (ECOG 1): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.848 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.751 mg/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 6.05 mmol/L.
- Day 408 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.937 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 5.03 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 7.1 mmol/L.
- Day 501 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.797 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 6.36 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 4.95 mmol/L.
- Day 600: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 7.23 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6 g/dL; Glucose 6.49 mmol/L.
- Day 653: M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.831 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.987 mg/dL; Immunoglobulin G 7.31 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 4.79 mmol/L.
- Day 809 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 7 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -32: Weight: 105 kg; Height: 182 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2353_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -32 days.
- Sample MMRF_2353_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -32 days.
